Gene-level copy-number profile of tumor specimen TCGA-JY-A938-01A from TCGA case TCGA-JY-A938, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 75.7 years (27,633 days).
Specimen TCGA-JY-A938-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.673c4118-40ed-49bc-9708-455d12607b24.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-JY-A938-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a1068ddc-d762-4b1f-add3-e17276603062

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 18,489; copy number 2: 36,666; copy number 3: 3,523; copy number 4: 816; copy number 5: 214; copy number 6: 17; copy number 7: 51; copy number 8: 39.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-JY-A938-01A-11D-A37B-01): tumor purity 0.42, ploidy 1.84, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:78,495,926–78,553,296, 4 genes (within-gene range 0–1): AC046158.1, AC046158.4, AC046158.2, AC046158.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 321 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,096–2,462,942, 89 genes, copy number 7–8 (broad region; genes not listed).
- chr4:2,463,797–2,464,124, 1 gene, copy number 7: AL645924.1.
- chr6:127,968,785–128,520,616, 1 gene, copy number 6 (within-gene range 4–6): PTPRK.
- chr6:128,500,527–129,820,170, 16 genes, copy number 6: AL034349.1, EEF1DP5, Y_RNA, AL080315.1, Y_RNA, LAMA2, MESTP1, BMPR1AP1, RNU6-861P, AL356124.1, AL356124.2, ARHGAP18, RPL5P21, AL451046.2, B3GALNT2P1, AL451046.1.
- chr6:134,520,163–137,544,372, 57 genes, copy number 5 (within-gene range 4–5): AL078590.2, FAM8A6P, AL078590.1, AL596188.1, AL121970.1, MEMO1P2, ALDH8A1, AL445190.1, HBS1L, MIR3662, AL353596.1, MYB, MYB-AS1, MIR548A2, AL023693.1, AHI1, AL049552.1, AL049552.2, Y_RNA, LINC00271, GAPDHP73, AL035604.1, HMGB1P17, AL133319.1, PDE7B, AL360178.1, AL360178.2, AL138828.1, COX5BP2, AL138828.2, MTFR2, BCLAF1, AL023284.1, AL023284.4, MAP7, AL023284.3, AL023284.2, NDUFS5P1, RN7SKP299, AL024508.1, MAP3K5, MAP3K5-AS1, RNA5SP219, AL121933.2, PEX7, AL121933.1, AL365223.1, SLC35D3, Y_RNA, RPL35AP3, NHEG1, AL135902.1, IL20RA, IL22RA2, IFNGR1, OLIG3, BTF3L4P3.
- chr17:38,530,031–41,140,487, 148 genes, copy number 5 (broad region; genes not listed).
- chr20:23,583,645–23,745,524, 9 genes, copy number 5 (within-gene range 3–5): CST9LP2, CST9, CST3, AL121894.2, AL121894.1, AL121894.3, CST4, CST2P1, AL591074.2.

Autosomal genes at a single copy (total copy number 1): 16,579. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
